Somatic mutation profile of tumor specimen C3N-02188-03 (aliquot CPT0168830006) from CPTAC case C3N-02188, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.4 years (21,709 days).
Specimen C3N-02188-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fbfa73c-3fef-4f96-be6e-ddcd95f70503.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02188-71 (Blood Derived Normal), aliquot CPT0168870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23c35798-5ee7-4c83-9be5-4b03d19d8889

The open-access MAF lists 68 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 14, Intron 6, RNA 5, Nonsense Mutation 1, 3'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A2 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373072443, CM098044; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AKR1B15 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as rs375218589, COSV71151018; called by muse, mutect2, varscan2
- AQP10 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.468); catalogued as rs768207751, COSV61476104; called by muse, mutect2, varscan2
- CERS3 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs756608778; called by muse, mutect2, varscan2
- COL1A2 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 105/671 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs746187799, COSV51967474; called by muse, mutect2, varscan2
- FCRL3 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs1310278446; called by muse, mutect2, varscan2
- HTR1B | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64051593; called by muse, mutect2, varscan2
- KCND1 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs781904171; called by muse, mutect2, varscan2
- KIT | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 102/1346 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs1060502556, CM1313110, COSV55391254, COSV55433753; ClinVar: uncertain significance; called by muse, mutect2
- MAB21L4 | c.1181C>T p.A394V (on ENST00000388934 / NM_001085437.3; = p.A226V on NM_024861.4) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs200054227; called by muse, mutect2, varscan2
- MAP3K7 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.569); catalogued as rs369978696; called by muse, mutect2, varscan2
- MAPK15 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs201591856; called by muse, mutect2, varscan2
- MTMR7 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as rs748679120, COSV51670518; called by muse, mutect2, varscan2
- MUC12 | c.2111C>A p.T704K (on ENST00000379442; = p.T561K on NM_001164462.1) | Missense Mutation (SNP) | VAF 71/382 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs1177602133; called by muse, mutect2, varscan2
- NEB | c.12797C>T p.T4266M | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778982089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP2 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 113/437 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1277670847; called by muse, mutect2, varscan2
- NPAS4 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs749883401, COSV60649002; called by muse, mutect2, varscan2
- OGDHL | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.075); catalogued as rs750135745; called by muse, mutect2, varscan2
- RADX | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as rs202230345; called by muse, mutect2, varscan2
- SCG2 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs368049148; called by muse, mutect2, varscan2
- SCML4 | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 29/141 reads (21%) | catalogued as COSV64637152; called by muse, mutect2, varscan2
- SCN7A | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs369751581, COSV101313377, COSV69275976; called by muse, mutect2, varscan2
- SERTAD2 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs765626048; called by muse, mutect2, varscan2
- SLC22A6 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1289616706, COSV64560224; called by muse, mutect2, varscan2
- SUGCT | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.622); catalogued as rs754469982, COSV100004552; called by muse, mutect2, varscan2
- TTN | c.61939C>T p.R20647C (on ENST00000591111; = p.R13223C on NM_003319.4) | Missense Mutation (SNP) | VAF 93/347 reads (27%) | PolyPhen probably damaging (0.998); catalogued as rs367665060; called by muse, mutect2, varscan2
- UNC13C | c.2906G>A p.R969H | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs767197055, COSV52849522, COSV99522515; called by muse, mutect2, varscan2
- ZNF526 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs750223739, COSV55898399, COSV55900675; called by muse, mutect2, varscan2
- ZSCAN5C | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs994017540, COSV66186762; called by muse, mutect2, varscan2
- AKAP14 | c.100del p.D34Mfs*3 | Frame Shift Del (DEL) | VAF 55/130 reads (42%) | called by mutect2, pindel, varscan2
- ANKRD50 | c.3461C>T p.P1154L | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARPP21 | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CEP162 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DCAF12L1 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2S3B | c.795C>A p.N265K | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- FOXA1 | c.1361C>A p.A454D | Missense Mutation (SNP) | VAF 89/348 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- GLIPR1L2 | c.687C>A p.D229E | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- KCNT1 | c.1615G>A p.G539S (on ENST00000488444; = p.G558S on NM_020822.3) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- KIF2B | c.1252G>T p.V418F | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- RAD9A | c.747C>G p.F249L | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SPAG17 | c.5260G>T p.G1754C | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- TBK1 | c.1248+6T>C | Splice Region (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- AGAP2 | c.324C>T p.P108= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- CCDC166 | c.948G>A p.S316= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs1351337262, COSV72638734; called by muse, mutect2, varscan2
- CEMIP | c.2433T>C p.N811= | Silent (SNP) | VAF 129/544 reads (24%) | called by muse, mutect2, varscan2
- DLX5 | c.207T>A p.A69= | Silent (SNP) | VAF 55/407 reads (14%) | called by muse, mutect2, varscan2
- GDF3 | c.912T>C p.S304= | Silent (SNP) | VAF 40/157 reads (25%) | called by muse, mutect2, varscan2
- GLRA1 | c.99C>G p.P33= | Silent (SNP) | VAF 103/364 reads (28%) | called by muse, mutect2, varscan2
- LAMB1 | c.4317C>T p.N1439= | Silent (SNP) | VAF 88/599 reads (15%) | catalogued as rs143816350; called by muse, mutect2, varscan2
- LYPD8 | c.606C>T p.N202= | Silent (SNP) | VAF 108/419 reads (26%) | called by muse, mutect2, varscan2
- MICU3 | c.1116A>G p.L372= | Silent (SNP) | VAF 14/62 reads (23%) | called by muse, mutect2, varscan2
- NRXN2 | c.2487C>A p.V829= | Silent (SNP) | VAF 103/409 reads (25%) | called by muse, mutect2, varscan2
- OR56A1 | c.651C>T p.I217= | Silent (SNP) | VAF 52/226 reads (23%) | called by mutect2, varscan2
- TTC6 | c.3366G>A p.A1122= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs774141984; called by muse, mutect2, varscan2
- USP20 | c.2022C>T p.N674= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as rs375361283; called by muse, mutect2, varscan2
- XPOT | c.1695T>C p.D565= | Silent (SNP) | VAF 47/165 reads (28%) | called by muse, mutect2, varscan2
- AC002511.3 | n.334_337del | RNA (DEL) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- ADAMTS8 | chr11:130401886 G>T | 3'Flank (SNP) | VAF 98/366 reads (27%) | called by muse, mutect2, varscan2
- DMD | c.2292+57G>A | Intron (SNP) | VAF 39/77 reads (51%) | catalogued as rs749294351, COSV99926501; called by muse, mutect2, varscan2
- DPY19L2P1 | n.1811+1572G>A | Intron (SNP) | VAF 20/118 reads (17%) | catalogued as rs756994626; called by muse, mutect2, varscan2
- FOXP2 | c.258+3666C>T | Intron (SNP) | VAF 55/293 reads (19%) | catalogued as rs566593208; called by muse, mutect2, varscan2
- LINC01193 | n.753G>T | RNA (SNP) | VAF 40/357 reads (11%) | called by muse, mutect2, varscan2
- LY9 | c.454+1821G>A | Intron (SNP) | VAF 35/135 reads (26%) | catalogued as rs775837935, COSV54433610; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.737C>T | RNA (SNP) | VAF 74/249 reads (30%) | called by muse, mutect2, varscan2
- OR2L1P | n.864C>T | RNA (SNP) | VAF 60/229 reads (26%) | catalogued as rs72763231; called by muse, mutect2, varscan2
- RANBP17 | c.2231+66G>A | Intron (SNP) | VAF 97/407 reads (24%) | catalogued as rs557711210; called by muse, mutect2, varscan2
- SSPOP | n.4558A>G | RNA (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2
- TCOF1 | c.378+22G>A | Intron (SNP) | VAF 16/182 reads (9%) | catalogued as rs773805454; called by muse, mutect2
